Somatic mutation profile of tumor specimen TCGA-BR-A4QM-01A (aliquot TCGA-BR-A4QM-01A-12D-A25D-08) from TCGA case TCGA-BR-A4QM, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 65.7 years (23,999 days).
Specimen TCGA-BR-A4QM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a539d64-485e-463b-9cda-65f54eebcd76.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-A4QM-10A (Blood Derived Normal), aliquot TCGA-BR-A4QM-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/85040b4e-c41a-4032-95a8-199fb1a5ca80

The open-access MAF lists 113 somatic variants for this specimen: 77 protein-altering or splice-affecting, 33 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 33, Nonsense Mutation 5, Frame Shift Del 2, RNA 1, Frame Shift Ins 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH1 | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1567508990, COSV55735504, COSV55737190, COSV55742643; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ERBB3 | c.889G>T p.D297Y | Missense Mutation (SNP) | VAF 31/134 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1057519891, COSV57247504, COSV57260861, COSV57263527; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RHOA | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 17/51 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.251); catalogued as rs1057519951, COSV69041613, COSV69042111, COSV69043712; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RNF43 | c.256C>T p.H86Y | Missense Mutation (SNP) | VAF 11/28 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV68456797; called by muse, mutect2, varscan2
- ADAD1 | c.1354C>A p.P452T | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV56646437; called by muse, mutect2, varscan2
- ADAMTS3 | c.2756A>G p.K919R | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.026); catalogued as rs759199903, COSV54399338; called by muse, mutect2, varscan2
- ATP13A1 | c.3290G>A p.S1097N | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV52290089; called by muse, mutect2, varscan2
- ATP1A3 | c.889C>A p.L297I (on ENST00000545399 / NM_001256214.2; = p.L284I on NM_152296.5) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV57490368; called by muse, mutect2, varscan2
- BTBD11 | c.205G>A p.V69I | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.581); catalogued as COSV55033894; called by muse, mutect2, varscan2
- CACNB2 | c.484C>T p.R162* (on ENST00000324631 / NM_201596.3; = p.R107* on NM_000724.4) | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | catalogued as rs1257625518, COSV56640971; called by muse, mutect2, varscan2
- CCER1 | c.241G>A p.V81M | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as rs768934116, COSV62648259; called by muse, mutect2
- CCT6B | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV58491126; called by muse, mutect2
- CD1C | c.637C>A p.R213S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV63807285; called by muse, mutect2, varscan2
- CNBD1 | c.1187T>A p.L396H | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV73072298, COSV73072404, COSV73073941; called by muse, mutect2, varscan2
- CSMD2 | c.7499G>A p.R2500H | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs775395186, COSV53948163; called by muse, mutect2, varscan2
- DCAF4L2 | c.332A>G p.E111G | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.041); catalogued as COSV60481455; called by muse, mutect2, varscan2
- DCC | c.2365A>C p.S789R | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59125955; called by muse, mutect2, varscan2
- DGKI | c.2066C>A p.A689D | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.211); catalogued as COSV55969283; called by muse, mutect2, varscan2
- DHX15 | c.718A>G p.M240V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV61028645; called by muse, mutect2, varscan2
- DNAH9 | c.7129G>T p.A2377S | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.607); catalogued as rs1048049959, COSV52369612; called by muse, mutect2, varscan2
- EPHA3 | c.2854A>G p.K952E | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.95); PolyPhen probably damaging (0.987); catalogued as rs1156599993, COSV100346584; called by mutect2, varscan2
- ESRRG | c.236T>G p.L79R | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.979); catalogued as COSV63175751; called by muse, mutect2
- FAT4 | c.8587T>G p.F2863V | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.991); catalogued as COSV58695383; called by muse, mutect2
- FICD | c.949G>A p.G317R | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770607435, COSV57209932; called by muse, mutect2, varscan2
- FLG2 | c.5656A>C p.S1886R | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.326); catalogued as COSV66171766; called by muse, mutect2, varscan2
- FNDC4 | c.232T>G p.Y78D | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV53022391; called by muse, mutect2, varscan2
- GNPTAB | c.3592C>A p.L1198M | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100172130; called by muse, mutect2
- GPC5 | c.637G>A p.G213R | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.27); catalogued as COSV65620729; called by muse, mutect2, varscan2
- GPR61 | c.1108C>A p.L370M | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); catalogued as COSV100879917; called by muse, mutect2
- GRHL3 | c.1408C>T p.R470C (on ENST00000350501 / NM_198174.3; = p.R475C on NM_021180.3) | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1057164040, COSV52570112; called by muse, mutect2, varscan2
- HYDIN | c.6220G>C p.A2074P | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59266553; called by muse, mutect2, varscan2
- KCNA4 | c.1252A>G p.T418A | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.262); catalogued as rs1263990356, COSV60255079; called by muse, mutect2, varscan2
- KRTAP10-10 | c.743A>T p.K248M | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV59974882; called by muse, mutect2, varscan2
- LAMA1 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.059); catalogued as COSV67542573; called by muse, mutect2, varscan2
- LPAR6 | c.126C>G p.F42L | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57321038; called by muse, mutect2, varscan2
- LRRC8B | c.2264T>C p.L755P | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58376603; called by muse, mutect2, varscan2
- LRRC8C | c.2159G>A p.S720N | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV65000298; called by muse, mutect2, varscan2
- MAPK8IP3 | c.3301G>A p.V1101I | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.987); catalogued as rs755178607, COSV51602406; called by muse, mutect2, varscan2
- MEF2C | c.1247C>T p.A416V | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.244); catalogued as rs768570497, COSV60937207; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MUC5B | c.5768C>T p.T1923M | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.125); catalogued as rs142667139; called by muse, mutect2, varscan2
- MYLK | c.4153C>T p.R1385C | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); catalogued as rs373683421; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NFIX | c.1121C>T p.T374M | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as rs1193070672, COSV62179868; called by muse, mutect2, varscan2
- OR2G2 | c.533A>G p.D178G | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs765341602, COSV60741788; called by muse, mutect2
- OR4A47 | c.274T>G p.F92V | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV71445096; called by muse, mutect2
- OTULIN | c.401C>T p.T134M | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375220163; called by muse, mutect2, varscan2
- PCDHA12 | c.1663G>A p.V555M | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs1554169356, COSV56501215, COSV56535448; called by muse, mutect2, varscan2
- PCDHB11 | c.749A>G p.K250R | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.012); catalogued as COSV99504598, COSV99505271; called by muse, mutect2, varscan2
- PCDHGB6 | c.1783G>A p.D595N | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99541707; called by mutect2, varscan2
- PRKD1 | c.526A>C p.K176Q | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV59580960; called by muse, mutect2, varscan2
- PTPN13 | c.1444C>T p.R482W | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs575836236, COSV57414713; called by muse, mutect2, varscan2
- RGS14 | c.1154T>A p.V385E | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as COSV68771812; called by muse, mutect2, varscan2
- RNF145 | c.95G>C p.S32T (on ENST00000424310 / NM_001199383.2; = p.S60T on NM_144726.2) | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.158); catalogued as COSV50870582; called by muse, mutect2, varscan2
- RNF43 | c.141dup p.I48Yfs*27 | Frame Shift Ins (INS) | VAF 11/36 reads (31%) | catalogued as COSV100090284; called by mutect2, pindel, varscan2
- ROBO1 | c.3314A>G p.Q1105R | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.159); catalogued as COSV71397456; called by muse, mutect2, varscan2
- RRP12 | c.3245A>G p.D1082G | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV59670649; called by muse, mutect2, varscan2
- SAMSN1 | c.706C>T p.R236* | Nonsense Mutation (SNP) | VAF 7/36 reads (19%) | catalogued as rs1028575264, COSV53475909; called by muse, mutect2, varscan2
- SLC11A1 | c.513G>T p.W171C | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51918764, COSV99262086; called by muse, mutect2, varscan2
- SLC39A11 | c.673G>T p.A225S (on ENST00000542342 / NM_001159770.2; = p.A218S on NM_139177.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.951); catalogued as COSV55298877; called by muse, mutect2, varscan2
- SYT14 | c.1537A>G p.R513G | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as COSV55061341; called by muse, mutect2, varscan2
- THEG | c.16C>T p.R6* | Nonsense Mutation (SNP) | VAF 13/42 reads (31%) | catalogued as rs201566887, COSV61074622; called by muse, mutect2, varscan2
- TLR10 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.86); PolyPhen benign (0.017); catalogued as rs762495806, COSV58301778; called by mutect2, varscan2
- TTN | c.11243T>A p.L3748H (on ENST00000591111; = p.L3702H on NM_003319.4) | Missense Mutation (SNP) | VAF 19/93 reads (20%) | catalogued as COSV60266066; called by muse, mutect2, varscan2
- UBQLN3 | c.1844A>C p.H615P | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV61165206; called by muse, mutect2, varscan2
- VIM | c.956A>G p.Y319C | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as COSV56407223; called by muse, mutect2, varscan2
- VSIG2 | c.367G>A p.V123I | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as rs775511402, COSV52519206; called by muse, mutect2, varscan2
- WNT3A | c.775C>T p.R259C | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV52733025; called by muse, mutect2, varscan2
- WSB2 | c.161C>A p.P54H | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.308); catalogued as COSV59574827; called by muse, mutect2, varscan2
- WSCD2 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.984); catalogued as COSV54589066; called by muse, mutect2, varscan2
- ZMIZ1 | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.936); catalogued as COSV57901811; called by muse, mutect2, varscan2
- ZNF281 | c.818C>T p.S273F | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV54169096; called by muse, mutect2, varscan2
- ZNF568 | c.1043A>C p.N348T | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.153); catalogued as COSV61742634; called by muse, mutect2, varscan2
- ZNF676 | c.265C>T p.Q89* (on ENST00000650058; = p.Q57* on NM_001001411.3) | Nonsense Mutation (SNP) | VAF 4/12 reads (33%) | catalogued as COSV68094463; called by muse, mutect2, varscan2
- ZNF80 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.326); catalogued as rs866579682, COSV57362231; called by muse, mutect2, varscan2
- GLYR1 | c.257_272del p.V86Gfs*46 | Frame Shift Del (DEL) | VAF 6/62 reads (10%) | called by mutect2, pindel
- NIPA2 | c.850_853del p.S284Afs*22 | Frame Shift Del (DEL) | VAF 7/33 reads (21%) | called by mutect2, pindel, varscan2
- PRAMEF17 | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- WASHC2A | c.2521C>T p.Q841* | Nonsense Mutation (SNP) | VAF 9/60 reads (15%) | called by muse, mutect2, varscan2
- CA6 | c.801G>A p.Q267= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as COSV101077609; called by muse, mutect2
- CACNA2D3 | c.822C>T p.I274= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as rs748264157, COSV55567217; called by muse, mutect2, varscan2
- CHST2 | c.624C>T p.D208= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV58884657; called by muse, mutect2, varscan2
- CLEC2D | c.225C>T p.C75= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV51992691; called by muse, mutect2, varscan2
- CNOT3 | c.1782G>A p.P594= | Silent (SNP) | VAF 22/94 reads (23%) | catalogued as rs776931029, COSV55366965; called by muse, mutect2, varscan2
- COL2A1 | c.3249C>A p.G1083= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as COSV61533095; called by muse, mutect2, varscan2
- ETFBKMT | c.639A>T p.R213= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV55672650; called by muse, mutect2, varscan2
- FAT4 | c.849G>A p.A283= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV67896329; called by muse, mutect2, varscan2
- FLG | c.3219T>C p.D1073= | Silent (SNP) | VAF 79/330 reads (24%) | catalogued as rs771660324, COSV64246446; called by muse, mutect2, varscan2
- GRAMD1C | c.1230G>A p.R410= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV63983987; called by muse, mutect2, varscan2
- HEATR1 | c.4737G>A p.A1579= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as rs369369261, COSV63981825; called by muse, mutect2, varscan2
- ITGA9 | c.912C>T p.F304= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as rs747663933, COSV53250023; called by muse, mutect2, varscan2
- KAT6B | c.4857C>T p.V1619= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV54752745; called by muse, mutect2, varscan2
- KCMF1 | c.669C>T p.S223= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs747547909, COSV69053428, COSV69053733; called by muse, mutect2, varscan2
- LVRN | c.99C>T p.L33= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV63498112; called by muse, mutect2, varscan2
- MCM10 | c.1671G>A p.S557= (on ENST00000484800 / NM_182751.3; = p.S556= on NM_018518.5) | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as rs377010061; called by muse, mutect2, varscan2
- MIB1 | c.2319T>A p.G773= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV55093776; called by muse, mutect2, varscan2
- MRGPRE | c.102C>T p.L34= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs374299149, COSV67745879; called by muse, mutect2, varscan2
- MUC16 | c.16527T>C p.S5509= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV67446521, COSV67464155; called by mutect2, varscan2
- OR2Y1 | c.438C>T p.I146= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs776114957, COSV57137631; called by muse, mutect2, varscan2
- PCDHA5 | c.2052C>T p.G684= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as rs1554129619, COSV65356030; called by muse, mutect2, varscan2
- PCDHB8 | c.1279T>C p.L427= | Silent (SNP) | VAF 24/232 reads (10%) | catalogued as COSV50803663; called by muse, mutect2
- PLXNB3 | c.2578C>T p.L860= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as rs781994283, COSV62800898; called by muse, mutect2, varscan2
- RIMS2 | c.1342T>C p.L448= (on ENST00000666250 / NM_001348490.2; = p.L256= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as COSV51669105, COSV51676746; called by muse, mutect2, varscan2
- RSPH6A | c.1524C>T p.D508= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs753394317, COSV55574415; called by muse, mutect2, varscan2
- SCN5A | c.2013C>T p.S671= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as rs751050999, COSV61135167; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SEC23IP | c.378C>T p.S126= | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as COSV64832687; called by muse, mutect2, varscan2
- SYCP2 | c.4398T>G p.T1466= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV62765939; called by mutect2, varscan2
- UBR2 | c.2919G>A p.L973= | Silent (SNP) | VAF 70/125 reads (56%) | catalogued as COSV65751926; called by muse, mutect2, varscan2
- UNC13C | c.3985T>C p.L1329= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as COSV52842755, COSV52856856; called by muse, mutect2, varscan2
- WDFY3 | c.6249A>T p.S2083= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV55710968; called by muse, mutect2
- WDR13 | c.405C>T p.S135= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs1442800794, COSV54333073; called by muse, mutect2, varscan2
- ZNF423 | c.1323C>T p.H441= (on ENST00000563137 / NM_001379286.1; = p.H433= on NM_015069.4) | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as rs777932033, COSV52175395; called by muse, mutect2, varscan2
- CABYR | c.*17-344C>T | Intron (SNP) | VAF 13/44 reads (30%) | catalogued as COSV100112167; called by muse, mutect2, varscan2
- DCHS2 | n.6650C>A | RNA (SNP) | VAF 5/27 reads (19%) | catalogued as COSV61772572, COSV61777760; called by muse, mutect2, varscan2
- KRTAP21-2 | c.-1C>A | 5'UTR (SNP) | VAF 13/60 reads (22%) | catalogued as COSV100441228; called by muse, mutect2, varscan2
